MMRF case MMRF_1855 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/41b8e05c-b5fe-45b8-bc9e-214ea4b35e0a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.5 years (22,841 days); ISS stage: I; Days to last known disease status: 826 days (2.3 years); Days to last follow up: 826 days (2.3 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 183 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 183 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 184 days; Days to treatment end: 239 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 240 days; Days to treatment end: 882 days (2.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.45 mg/dL; Immunoglobulin G 2.99 g/L; Immunoglobulin A 14.4 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.55 mmol/L; Albumin 40 g/L; Total Protein 8.1 g/dL; Glucose 4.95 mmol/L; C-Reactive Protein 0.059 mg/dL.
- Day 92 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 2.17 g/L; Immunoglobulin A 2.26 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 16.8 ×10⁹/L; Absolute Neutrophil 13 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 5.9 g/dL; Glucose 5.56 mmol/L.
- Day 183 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 1.8 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 11.1 ×10⁹/L; Absolute Neutrophil 10 ×10⁹/L; Platelets 315 ×10⁹/L; Creatinine 43.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.
- Day 260 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 2.39 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.5 mmol/L; Albumin 46 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.
- Day 351 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.26 mg/dL; Immunoglobulin G 4.75 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 43.3 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 4.62 mmol/L.
- Day 463 (ECOG 0): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 4.43 g/L; Immunoglobulin A 1.36 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 4.62 mmol/L.
- Day 548 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 5.03 g/L; Immunoglobulin A 1.65 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 5.01 mmol/L.
- Day 629 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 4.68 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 5.17 mmol/L.
- Day 715 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 4.7 g/L; Immunoglobulin A 2.43 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 4.29 mmol/L.
- Day 826 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 4.94 g/L; Immunoglobulin A 3.45 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.01 mmol/L.

Other clinical attributes
- Day -6: Weight: 67 kg; Height: 160 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1855_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1855_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
